Somatic mutation profile of tumor specimen TCGA-HT-7601-01A (aliquot TCGA-HT-7601-01A-11D-2086-08) from TCGA case TCGA-HT-7601, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Brain, NOS; Tumor grade: G3; Age at diagnosis: 30.1 years (10,989 days).
Specimen TCGA-HT-7601-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a36d79bb-7156-4448-b725-5fdd2011860f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-7601-10A (Blood Derived Normal), aliquot TCGA-HT-7601-10A-01D-2086-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a87faa0a-3f43-48e0-868d-ed7b8610630a

The open-access MAF lists 24 somatic variants for this specimen: 18 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 15, Silent 6, Translation Start Site 1, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 36/142 reads (25%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 22/35 reads (63%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABTB2 | c.2278C>T p.R760W | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs966151779, COSV54396677; called by muse, mutect2
- AKAP4 | c.1860C>G p.D620E | Missense Mutation (SNP) | VAF 10/277 reads (4%) | SIFT tolerated (0.64); PolyPhen benign (0.015); catalogued as COSV62075624; called by muse, mutect2
- COL14A1 | c.1907C>T p.T636M | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs771290485, COSV52850061; called by muse, mutect2, varscan2
- HEPHL1 | c.2195T>C p.I732T | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as rs774577612, COSV59891101; called by muse, mutect2, varscan2
- IFNA21 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs776674981, COSV66519082; called by muse, mutect2, varscan2
- IPO5 | c.1571A>G p.E524G | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.768); catalogued as COSV55160322; called by muse, mutect2
- KCNB2 | c.1492G>C p.A498P | Missense Mutation (SNP) | VAF 42/154 reads (27%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.828); catalogued as COSV73053225; called by muse, mutect2, varscan2
- KLHL13 | c.1927A>C p.T643P | Missense Mutation (SNP) | VAF 13/171 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV53253837; called by muse, mutect2
- LIPE | c.724T>A p.S242T | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.05); catalogued as COSV54925948; called by muse, mutect2, varscan2
- MCTP2 | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.745); catalogued as rs751656768, COSV59151239; called by muse, mutect2, varscan2
- NOM1 | c.527T>C p.L176S | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV51983157; called by muse, mutect2
- PLD1 | c.1043A>G p.E348G | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1375847662, COSV60574804; called by muse, mutect2, varscan2
- PRKAR1A | c.789A>T p.E263D | Missense Mutation (SNP) | VAF 15/153 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV62236616; called by muse, mutect2, varscan2
- SLC6A4 | c.418G>A p.G140R | Missense Mutation (SNP) | VAF 71/228 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55570119; called by muse, mutect2, varscan2
- SMARCE1 | c.312G>A p.W104* | Nonsense Mutation (SNP) | VAF 8/168 reads (5%) | catalogued as COSV52861912; called by muse, mutect2
- ACVRL1 | c.773-6_774del p.X258_splice | Splice Site (DEL) | VAF 10/45 reads (22%) | called by mutect2, pindel, varscan2
- APBB2 | c.825G>A p.P275= | Silent (SNP) | VAF 58/220 reads (26%) | catalogued as rs1325619270, COSV55963923; called by muse, mutect2, varscan2
- CPNE2 | c.285C>G p.L95= | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as COSV51965407; called by muse, mutect2, varscan2
- LIPE | c.723T>A p.S241= | Silent (SNP) | VAF 43/108 reads (40%) | catalogued as COSV54925959; called by muse, mutect2, varscan2
- LLGL2 | c.2247G>A p.V749= | Silent (SNP) | VAF 9/100 reads (9%) | catalogued as COSV51417714; called by muse, mutect2
- PITPNM1 | c.405G>A p.Q135= | Silent (SNP) | VAF 26/88 reads (30%) | catalogued as rs1430609371, COSV56874703; called by muse, mutect2, varscan2
- WASHC5 | c.1368C>G p.V456= | Silent (SNP) | VAF 67/206 reads (33%) | catalogued as COSV59201037; called by muse, mutect2, varscan2
